Somatic mutation profile of tumor specimen 0DLRHU from CCDI case PBBZLT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.0 years (2,561 days).
Specimen 0DLRHU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ba4e3f1-9f07-443f-93ad-d717c2796af3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLRHK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cc21106-d793-4746-b372-aa0513b4f217

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUTM2D | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 587/2900 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs373281825; called by muse, varscan2
- PCDH11Y | c.2456G>A p.R819H (on ENST00000400457 / NM_032973.2; = p.R808H on NM_032971.3) | Missense Mutation (SNP) | VAF 628/708 reads (89%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs755210662, COSV53077594; called by muse, varscan2
- MED25 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 382/815 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.286); called by muse, varscan2
- GTF2IRD1 | c.459C>A p.P153= | Silent (SNP) | VAF 126/456 reads (28%) | called by muse, varscan2
- TMEM240 | c.-16G>A | 5'UTR (SNP) | VAF 29/223 reads (13%) | called by muse, varscan2
